Somatic mutation profile of tumor specimen MP2PRT-PASHTE-TMP1-A (aliquot MP2PRT-PASHTE-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASHTE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,631 days).
Specimen MP2PRT-PASHTE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28e0fc05-1c3e-48f8-a8a6-e3780af5b73a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASHTE-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASHTE-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be11c7aa-82d7-4f32-a12a-f42aeab50dff

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE4 | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV70194162; called by muse, mutect2
- DMRT1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 168/435 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.508); catalogued as rs767829750; called by muse, varscan2
- EEF1G | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs766058630; called by muse, mutect2, varscan2
- ITGB4 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 42/630 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281055164; called by muse, mutect2
- OVCH1 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.465); catalogued as COSV99041024; called by muse, mutect2, varscan2
- PHEX | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 165/437 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs765714025, COSV65074117; called by muse, mutect2, varscan2
- UBA2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 150/414 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV99875133; called by muse, mutect2, varscan2
- ZP2 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs534452053; called by muse, mutect2, varscan2
- CETP | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 150/346 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGHV3-53 | c.347_348insTTCAG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 44/77 reads (57%) | called by pindel, varscan2
- TBL1XR1 | c.420_422delinsGG p.I141Efs*8 | Frame Shift Del (DEL) | VAF 128/270 reads (47%) | called by pindel, varscan2*
- GATA4 | c.1074C>T p.S358= | Silent (SNP) | VAF 38/379 reads (10%) | catalogued as rs375407669, CD041915; ClinVar: likely benign; called by muse, varscan2
- KCNC4 | c.1122G>A p.L374= | Silent (SNP) | VAF 140/468 reads (30%) | called by muse, mutect2, varscan2
- KRT1 | c.1308C>T p.A436= | Silent (SNP) | VAF 29/556 reads (5%) | catalogued as COSV52866920; called by muse, mutect2
- RFX3 | c.1209G>A p.L403= | Silent (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
